Somatic mutation profile of tumor specimen MP2PRT-PAPZRA-TMP1-A (aliquot MP2PRT-PAPZRA-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPZRA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,448 days).
Specimen MP2PRT-PAPZRA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60b59686-71f3-43c6-80ad-0f0d121a8d37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZRA-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZRA-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae26f7bd-2960-4432-ad7d-f7cf33ca0a47

The open-access MAF lists 49 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Nonsense Mutation 2, 3'Flank 2, Splice Region 1, Frame Shift Ins 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 42/222 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RECQL4 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 51/399 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs771349728, COSV100020571, COSV56742668; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs544243571; called by muse, mutect2, varscan2
- C1QBP | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV56579009; called by muse, mutect2, varscan2
- CDH8 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1349388080; called by muse, mutect2, varscan2
- COL11A1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as rs762173332; called by muse, mutect2, varscan2
- DOCK1 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs759611299; called by muse, mutect2, varscan2
- GPT | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 94/550 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs910044306, COSV99477963; called by muse, mutect2, varscan2
- GRM3 | c.1323G>A p.T441= | Splice Region (SNP) | VAF 9/115 reads (8%) | catalogued as rs1465764905, COSV100862565; called by muse, mutect2
- GTF3C5 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 76/497 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59600793; called by muse, mutect2, varscan2
- LAMA2 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 45/176 reads (26%) | catalogued as rs868019991, COSV70351944; called by muse, mutect2, varscan2
- LPO | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867152504; called by muse, mutect2
- NCKAP1 | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62940174; called by muse, mutect2, varscan2
- OPN5 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as rs1370710652, COSV55244312; called by muse, mutect2, varscan2
- OR8G1 | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.109); catalogued as COSV100422373; called by muse, mutect2, varscan2
- PWWP3B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV61800293; called by muse, mutect2, varscan2
- TAF1L | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs766498802; called by muse, mutect2, varscan2
- ZNF479 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100482489, COSV58635651, COSV58636836; called by muse, mutect2, varscan2
- ABCA13 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CDH1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COG5 | c.1865G>C p.R622T (on ENST00000347053 / NM_001379512.1; = p.R643T on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- DLD | c.1524C>A p.N508K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT2 | c.6170G>C p.R2057T | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- FSIP2 | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GGNBP2 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- GLDN | c.1381C>A p.Q461K | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- HNRNPH3 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- IGHV3-53 | c.349_350insCCGCATGAGAG | Nonsense Mutation (INS) | VAF 10/65 reads (15%) | called by pindel, varscan2*
- KLHL33 | c.777dup p.G260Rfs*14 | Frame Shift Ins (INS) | VAF 108/348 reads (31%) | called by mutect2, pindel, varscan2
- NBEA | c.8583C>G p.I2861M | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- PKHD1 | c.10395C>G p.I3465M | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- REEP3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- SLC12A9 | c.1333C>G p.P445A | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UNC80 | c.2216A>G p.D739G | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPRS1 | c.2892G>A p.K964= | Silent (SNP) | VAF 30/186 reads (16%) | called by muse, mutect2, varscan2
- KDM4E | c.852C>T p.F284= | Silent (SNP) | VAF 28/187 reads (15%) | catalogued as rs1369767174; called by muse, mutect2, varscan2
- LRRC14 | c.1075C>T p.L359= | Silent (SNP) | VAF 49/287 reads (17%) | called by muse, mutect2, varscan2
- LRRC4C | c.1545G>A p.G515= | Silent (SNP) | VAF 51/208 reads (25%) | catalogued as COSV53430430; called by muse, mutect2, varscan2
- PCDHGB5 | c.1353G>A p.A451= | Silent (SNP) | VAF 48/247 reads (19%) | catalogued as COSV53975217; called by muse, mutect2, varscan2
- RASAL3 | c.1338C>T p.L446= | Silent (SNP) | VAF 17/541 reads (3%) | called by muse, mutect2
- SCNN1G | c.1650C>T p.I550= | Silent (SNP) | VAF 54/270 reads (20%) | catalogued as rs370729372; called by muse, mutect2, varscan2
- SERPINC1 | c.345C>A p.I115= | Silent (SNP) | VAF 41/209 reads (20%) | called by muse, mutect2, varscan2
- SSU72P5 | c.498C>T p.D166= | Silent (SNP) | VAF 56/207 reads (27%) | catalogued as rs1347235004; called by muse, mutect2, varscan2
- TLR4 | c.447C>T p.L149= (on ENST00000355622 / NM_138554.5; = p.L109= on NM_003266.4) | Silent (SNP) | VAF 46/193 reads (24%) | catalogued as COSV62923379; called by muse, mutect2, varscan2
- XKR9 | c.238C>T p.L80= | Silent (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850728 del TGGGGGGTGGGGGTGGGGAGTTGGGGGGGT | 3'Flank (DEL) | VAF 2/17 reads (12%) | called by muse*, mutect2
- FXYD3 | c.-47C>T | 5'UTR (SNP) | VAF 83/400 reads (21%) | called by muse, mutect2, varscan2
- IGLV5-52 | chr22:22319226 ins TACC | 3'Flank (INS) | VAF 9/99 reads (9%) | called by mutect2, pindel*, varscan2*
- KCTD1 | c.-15-45904C>G | Intron (SNP) | VAF 76/327 reads (23%) | called by muse, mutect2, varscan2
